Somatic mutation profile of tumor specimen TCGA-24-1469-01A (aliquot TCGA-24-1469-01A-01W-0553-09) from TCGA case TCGA-24-1469, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.0 years (25,937 days).
Specimen TCGA-24-1469-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10f252b2-e715-4dc0-835a-c383391450a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1469-10A (Blood Derived Normal), aliquot TCGA-24-1469-10A-01W-0553-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a3ecf4a-cfc8-4c09-a723-211c316eb740

The open-access MAF lists 259 somatic variants for this specimen: 193 protein-altering or splice-affecting, 60 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 183, Silent 60, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 2, 5'UTR 2, Frame Shift Ins 2, RNA 2, 3'UTR 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADM | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121434278, CM940001; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 166/174 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3284G>C p.R1095P (on ENST00000272895 / NM_173076.3; = p.R777P on NM_015657.3) | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55961160, COSV55973178; called by muse, mutect2, varscan2
- ADAM10 | c.1841A>C p.Q614P | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99545286; called by muse, mutect2, varscan2
- ADAM32 | c.1603A>G p.R535G | Missense Mutation (SNP) | VAF 60/619 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1329530874, COSV101165161; called by muse, mutect2, varscan2
- ADCY9 | c.1748G>T p.C583F | Missense Mutation (SNP) | VAF 79/144 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV53580935; called by muse, mutect2, varscan2
- ADGRL3 | c.2782C>G p.L928V (on ENST00000506720 / NM_001322402.2; = p.L860V on NM_015236.6) | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72231772; called by muse, mutect2, varscan2
- ADSS1 | c.1165T>A p.F389I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV58275974; called by muse, mutect2
- AL121899.2 | c.1880G>A p.R627Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs374127604; called by muse, mutect2, varscan2
- ALMS1 | c.3226G>A p.V1076I | Missense Mutation (SNP) | VAF 64/642 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.053); catalogued as rs747559172, COSV100040627; called by muse, mutect2
- ALPP | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.059); catalogued as rs150250474; called by muse, varscan2
- ANKRD50 | c.1720G>C p.E574Q | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.658); catalogued as COSV101538852; called by muse, mutect2
- ANTXR1 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 102/471 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58020738; called by muse, mutect2, varscan2
- ARMC8 | c.541C>G p.Q181E (on ENST00000469044 / NM_001363941.2; = p.Q167E on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV100627429; called by muse, mutect2, varscan2
- ASB11 | c.770G>C p.R257T | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV60354282, COSV60356455; called by muse, mutect2, varscan2
- ASPH | c.754A>C p.T252P | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as COSV62861123; called by muse, mutect2, varscan2
- ASXL3 | c.6247C>T p.P2083S | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99322670; called by muse, mutect2
- ATF6 | c.1412T>C p.I471T | Missense Mutation (SNP) | VAF 35/299 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV63409835; called by muse, mutect2, varscan2
- ATP1A3 | c.1201C>T p.H401Y (on ENST00000545399 / NM_001256214.2; = p.H388Y on NM_152296.5) | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100131737; called by muse, mutect2
- B3GLCT | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58458068; called by muse, mutect2, varscan2
- B3GNT5 | c.950A>G p.E317G | Missense Mutation (SNP) | VAF 11/257 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100190639; called by muse, mutect2
- BHLHE40 | c.970C>G p.P324A | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56576398; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2518C>T p.R840W | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as rs758046666; called by muse, mutect2
- BPIFB4 | c.1174A>C p.I392L | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV100971368; called by muse, mutect2
- BPTF | c.6112G>C p.V2038L | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV100073515; called by muse, mutect2, varscan2
- BRINP2 | c.956G>C p.S319T | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100837767; called by muse, mutect2, varscan2
- C11orf45 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV100171446; called by muse, mutect2
- C5AR1 | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV61892549; called by muse, mutect2, varscan2
- C8orf33 | c.545G>C p.R182T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV100510438; called by muse, varscan2
- C9orf64 | c.787C>G p.L263V | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as COSV100123465, COSV59033198; called by muse, mutect2
- CAMK1D | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101123325; called by muse, mutect2
- CAMK1G | c.1021C>G p.Q341E | Missense Mutation (SNP) | VAF 45/456 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99151625; called by muse, mutect2
- CCDC138 | c.1105C>G p.H369D | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV54571355; called by muse, mutect2, varscan2
- CCDC73 | c.71C>G p.S24C | Missense Mutation (SNP) | VAF 50/612 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100065981; called by muse, mutect2
- CCNJ | c.328A>C p.N110H | Missense Mutation (SNP) | VAF 5/120 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99796103; called by muse, mutect2
- CCNL1 | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as COSV99904335; called by muse, mutect2
- CDH12 | c.2089T>A p.S697T | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV101200558; called by muse, mutect2
- CHRM2 | c.44C>G p.T15R | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV57775035, COSV57782840; called by muse, mutect2, varscan2
- CHRM2 | c.1161G>T p.R387S | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV57770486, COSV57782849; called by muse, mutect2, varscan2
- COL4A2 | c.4823C>T p.S1608F | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100846997; called by muse, mutect2, varscan2
- COL6A3 | c.4437G>T p.Q1479H | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55106291; called by muse, mutect2, varscan2
- COLEC12 | c.798G>C p.Q266H | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68373318; called by muse, mutect2, varscan2
- CUBN | c.7570G>C p.E2524Q | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as COSV100911717; called by muse, mutect2
- CYP2A6 | c.18G>A p.M6I | Missense Mutation (SNP) | VAF 87/336 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV56536964; called by muse, mutect2, varscan2
- DBN1 | c.1679C>G p.P560R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs1328499324, COSV99445335; called by muse, mutect2
- DDX21 | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.165); catalogued as COSV62556728; called by muse, mutect2, varscan2
- DIP2A | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as COSV59485840; called by muse, mutect2, varscan2
- DNM1L | c.1317G>T p.M439I | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV56777500; called by muse, mutect2, varscan2
- DOCK10 | c.6457G>T p.D2153Y | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV99286957; called by muse, mutect2
- DSG2 | c.1608A>T p.K536N | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV55202385; called by muse, mutect2, varscan2
- DSG3 | c.545C>A p.T182K | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99933538; called by muse, mutect2
- DST | c.9568G>A p.E3190K | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.025); catalogued as COSV55036487; called by muse, mutect2, varscan2
- EGFLAM | c.885del p.K296Rfs*23 | Frame Shift Del (DEL) | VAF 41/338 reads (12%) | catalogued as COSV59317591; called by mutect2, pindel, varscan2
- EIF2B5 | c.811A>G p.N271D (on ENST00000647909; = p.N263D on NM_003907.3) | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV56606062; called by muse, mutect2, varscan2
- EMC1 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.817); catalogued as COSV61887076; called by muse, mutect2, varscan2
- ESS2 | c.440G>T p.S147I | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV52816150; called by muse, mutect2, varscan2
- EZH1 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1260794915, COSV52853871; called by muse, mutect2, varscan2
- F2RL2 | c.16T>G p.F6V | Missense Mutation (SNP) | VAF 83/546 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV56971950; called by muse, mutect2, varscan2
- FAM120C | c.2839G>A p.G947S | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.636); catalogued as COSV100069412, COSV60257604; called by muse, mutect2
- FAP | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51866872; called by muse, mutect2, varscan2
- FASTKD1 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV71624797; called by muse, mutect2
- FAT4 | c.5602G>A p.D1868N | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV58705266; called by muse, mutect2, varscan2
- FBXO7 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV56681044; called by muse, mutect2, varscan2
- FLG | c.2051A>C p.H684P | Missense Mutation (SNP) | VAF 56/585 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV100910239, COSV64251571; called by muse, mutect2
- FRAS1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs568676550, COSV53611295; called by muse, mutect2, varscan2
- FRK | c.361A>G p.I121V | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV73384208; called by muse, mutect2, varscan2
- G6PD | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.897); catalogued as COSV63704314; called by muse, mutect2, varscan2
- GABRA5 | c.1157dup p.N387Kfs*23 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | catalogued as rs779873187; called by pindel, varscan2
- GJB4 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV58356994; called by muse, mutect2, varscan2
- GNAL | c.1007G>C p.S336T (on ENST00000269162 / NM_001142339.3; = p.S413T on NM_182978.4) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); catalogued as COSV52333116; called by muse, mutect2, varscan2
- GNAZ | c.612dup p.Q205Afs*35 | Frame Shift Ins (INS) | VAF 13/88 reads (15%) | catalogued as rs752075537; called by mutect2, varscan2
- GRIN2A | c.3660C>G p.N1220K | Missense Mutation (SNP) | VAF 17/308 reads (6%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV100407226; called by muse, mutect2
- GRXCR1 | c.5T>A p.L2H | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.417); catalogued as COSV67670168, COSV67674256; called by muse, mutect2, varscan2
- H2BC17 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as rs114740219, COSV58153889; called by muse, mutect2, varscan2
- H2BC4 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as rs879122516, COSV58414927, COSV58416609, COSV58417570; called by muse, mutect2
- HAPLN3 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100613513; called by muse, mutect2
- HDAC3 | c.526G>C p.G176R | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59497422; called by muse, mutect2, varscan2
- HEPH | c.917C>T p.A306V (on ENST00000343002; = p.A39V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/91 reads (89%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV57970934; called by muse, mutect2, varscan2
- HEXB | c.1252G>C p.G418R | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54669635; called by muse, mutect2, varscan2
- HFM1 | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99644981; called by muse, mutect2
- HSP90AB1 | c.1398G>A p.M466I | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100806844; called by muse, mutect2
- IGSF10 | c.3959C>G p.A1320G | Missense Mutation (SNP) | VAF 99/1168 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99176516; called by muse, mutect2
- ITGA10 | c.2790G>C p.Q930H | Missense Mutation (SNP) | VAF 64/1027 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.066); catalogued as COSV100994605, COSV65195954; called by muse, mutect2
- JMJD1C | c.4262C>G p.S1421* | Nonsense Mutation (SNP) | VAF 16/190 reads (8%) | catalogued as COSV100550033; called by muse, mutect2
- KDM4C | c.1389C>A p.D463E | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101184588; called by muse, mutect2
- KIR2DL3 | c.33T>A p.V11= | Splice Region (SNP) | VAF 12/91 reads (13%) | catalogued as COSV52550795; called by muse, mutect2, varscan2
- KIR3DL2 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 1145/1242 reads (92%) | catalogued as rs912912797; called by muse, mutect2, varscan2
- LARP4B | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866154645, COSV60223537; called by muse, mutect2, varscan2
- LGALS3BP | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV53165950; called by muse, varscan2
- LRRC7 | c.2926G>C p.D976H (on ENST00000651989 / NM_001370785.2; = p.D943H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV50605295; called by muse, mutect2, varscan2
- LRTOMT | c.74T>A p.V25D | Missense Mutation (SNP) | VAF 64/684 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.066); catalogued as COSV99194362; called by muse, mutect2
- LYG2 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 100/1040 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.598); catalogued as COSV100283464, COSV60715782; called by muse, mutect2
- MACROD2 | c.867C>G p.N289K (on ENST00000642719; = p.N261K on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs373690455, COSV53993423, COSV99424879; called by muse, mutect2
- MAGEE1 | c.2158G>C p.E720Q | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV63911896; called by muse, mutect2, varscan2
- MAML2 | c.3442C>T p.L1148F | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73264603; called by muse, mutect2, varscan2
- MAML2 | c.1280G>T p.W427L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101593905; called by muse, mutect2, varscan2
- MLANA | c.94A>T p.I32F | Missense Mutation (SNP) | VAF 17/312 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as rs1178563464, COSV101199939; called by muse, mutect2
- MPP1 | c.843G>C p.K281N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as COSV65729383; called by muse, mutect2, varscan2
- MPP5 | c.1843A>T p.N615Y | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV55532205; called by muse, mutect2, varscan2
- MPZL2 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 43/636 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.232); catalogued as COSV99634913; called by muse, mutect2
- MSGN1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 64/84 reads (76%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs1048970746, COSV55263719; called by muse, mutect2, varscan2
- MYB | c.1540G>C p.E514Q | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.209); catalogued as COSV57201310; called by muse, mutect2, varscan2
- MYCBP2 | c.455A>T p.K152I (on ENST00000357337; = p.K190I on NM_015057.5) | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.177); catalogued as COSV100628743; called by muse, mutect2
- MYH1 | c.3286A>G p.S1096G | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV56856170; called by muse, mutect2, varscan2
- MYH4 | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99700032; called by muse, mutect2
- MYL10 | c.642C>G p.N214K | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99780889; called by muse, mutect2
- MYL12B | c.327C>G p.C109W | Missense Mutation (SNP) | VAF 23/325 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99410494; called by muse, mutect2
- MYOM2 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.704); catalogued as rs758822676, COSV100037002, COSV50732411; called by muse, mutect2
- NEBL | c.2604G>C p.M868I | Missense Mutation (SNP) | VAF 24/384 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV101009014; called by muse, mutect2
- NIBAN1 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV100836111; called by muse, mutect2
- NIM1K | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 52/716 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as COSV58140100; called by muse, mutect2
- NOVA1 | c.188C>A p.S63Y | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57483969, COSV99945846; called by muse, mutect2
- NTPCR | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs771511181, COSV100786730, COSV64052914; called by muse, mutect2, varscan2
- OR10G3 | c.83T>A p.F28Y | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100336046; called by muse, mutect2
- OR1E2 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as COSV99943330; called by mutect2, varscan2
- OR1N2 | c.95G>C p.G32A | Missense Mutation (SNP) | VAF 64/386 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.041); catalogued as COSV65461112; called by muse, mutect2, varscan2
- OTC | c.27A>T p.L9F | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV50001376; called by muse, mutect2, varscan2
- OTOGL | c.4778G>C p.G1593A (on ENST00000547103; = p.G1584A on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV100086378; called by muse, mutect2
- P2RY10 | c.697C>A p.Q233K | Missense Mutation (SNP) | VAF 284/310 reads (92%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV50685021; called by muse, mutect2, varscan2
- PAK3 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV53279824, COSV53280098; called by muse, mutect2, varscan2
- PARS2 | c.1345G>A p.V449I | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); catalogued as rs1162158690, COSV100988276; called by muse, mutect2
- PCDH9 | c.3224G>A p.G1075D (on ENST00000377865 / NM_203487.3; = p.G1041D on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.574); catalogued as COSV60584121; called by muse, mutect2, varscan2
- PCLO | c.5590G>C p.E1864Q | Missense Mutation (SNP) | VAF 16/484 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100425777; called by muse, mutect2
- PDE11A | c.2753C>A p.A918D | Missense Mutation (SNP) | VAF 64/286 reads (22%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.035); catalogued as COSV53706652; called by muse, mutect2, varscan2
- PDPR | c.589A>G p.S197G | Missense Mutation (SNP) | VAF 62/346 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1163732282, COSV99847535; called by muse, mutect2, varscan2
- PIP5K1A | c.1511G>T p.G504V (on ENST00000368888 / NM_001135638.2; = p.G491V on NM_003557.3) | Missense Mutation (SNP) | VAF 26/669 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100576416; called by muse, mutect2
- PIWIL3 | c.98C>G p.A33G | Missense Mutation (SNP) | VAF 104/332 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.221); catalogued as COSV59997833; called by muse, mutect2, varscan2
- PKHD1 | c.7561G>T p.A2521S | Missense Mutation (SNP) | VAF 97/208 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV100580875, COSV61892213; called by muse, mutect2, varscan2
- PKHD1 | c.5411G>A p.R1804H | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs151160618, CD149131; ClinVar: uncertain significance; called by muse, mutect2
- PLA2G4A | c.1326C>G p.H442Q | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs370896190, COSV66552649; called by muse, mutect2, varscan2
- PPM1L | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 36/512 reads (7%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV99861066; called by muse, mutect2
- PPP1R12A | c.827T>C p.I276T | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.524); catalogued as COSV54113421; called by muse, mutect2, varscan2
- PPP1R3A | c.468A>T p.L156F | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.291); catalogued as rs769328171, COSV52891049, COSV52891728; called by muse, mutect2, varscan2
- PPP4R3A | c.1791G>T p.M597I (on ENST00000554943 / NM_001366432.1; = p.M584I on NM_001284280.1) | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV61506317; called by muse, mutect2, varscan2
- PRPF40B | c.11C>T p.P4L (on ENST00000380281; = p.P26L on NM_001031698.3 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.981); catalogued as COSV99979137; called by muse, mutect2
- PRPF8 | c.2993G>C p.R998P | Missense Mutation (SNP) | VAF 46/49 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517915, COSV59267232; called by muse, mutect2, varscan2
- PSG3 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 104/895 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs905610494, COSV59506575; called by muse, mutect2, varscan2
- PSME4 | c.3856T>G p.Y1286D | Missense Mutation (SNP) | VAF 78/353 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV66367250; called by muse, mutect2, varscan2
- PTPN3 | c.1733T>G p.F578C | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52710299; called by muse, mutect2, varscan2
- PUM1 | c.1969A>G p.S657G | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV57090504; called by muse, mutect2, varscan2
- RB1 | c.2288G>C p.R763T | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV57324887; called by muse, mutect2, varscan2
- RBM12 | c.1183A>G p.M395V | Missense Mutation (SNP) | VAF 59/296 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV58294542; called by muse, mutect2, varscan2
- RBM28 | c.2063A>G p.K688R | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV56164643; called by muse, mutect2, varscan2
- RING1 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV100761692; called by muse, mutect2
- RNASEL | c.2027A>G p.E676G | Missense Mutation (SNP) | VAF 57/224 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.519); catalogued as COSV62377830; called by muse, mutect2, varscan2
- ROBO2 | c.4069G>T p.A1357S | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.01); catalogued as COSV100162961, COSV59897512; called by muse, mutect2
- SACS | c.4882C>T p.Q1628* | Nonsense Mutation (SNP) | VAF 46/95 reads (48%) | catalogued as COSV66546035; called by muse, mutect2, varscan2
- SAMD9 | c.3119G>T p.R1040L | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV66077310; called by muse, mutect2, varscan2
- SBF2 | c.2693G>A p.R898K | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99812506; called by muse, mutect2
- SF3A3 | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV100885571; called by muse, mutect2
- SIGLEC12 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 41/270 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV52464504; called by muse, mutect2, varscan2
- SIM1 | c.1737G>C p.E579D | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV53495372, COSV53496073; called by muse, mutect2, varscan2
- SORBS1 | c.1695A>T p.E565D | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.253); catalogued as COSV99527103; called by muse, mutect2, varscan2
- SOS2 | c.1939G>C p.E647Q | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV53573646; called by muse, mutect2, varscan2
- SPEG | c.476C>T p.T159M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs1348621476, COSV56678555; called by muse, mutect2, varscan2
- SPEN | c.752G>C p.R251T | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV65366878; called by muse, mutect2, varscan2
- SPHKAP | c.1319T>C p.V440A | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60892133; called by muse, mutect2, varscan2
- SPRY4 | c.89G>T p.R30L (on ENST00000434127 / NM_001127496.3; = p.R53L on NM_030964.4) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs759316507, COSV59986700; called by muse, mutect2, varscan2
- SPTA1 | c.5418G>T p.E1806D | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as COSV63750000; called by muse, mutect2, varscan2
- SSX3 | c.28A>G p.R10G | Missense Mutation (SNP) | VAF 60/664 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.49); catalogued as COSV100034872; called by muse, mutect2
- STAG1 | c.3223G>C p.V1075L | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.043); catalogued as COSV52622185, COSV52622549; called by muse, mutect2
- SYCP2L | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51657035; called by muse, mutect2, varscan2
- TLR10 | c.2404A>G p.T802A | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV100457313; called by muse, mutect2
- TOP1 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 58/296 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.069); catalogued as COSV63695837; called by muse, mutect2, varscan2
- TREML2 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101530134; called by muse, mutect2
- TREML2 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV72439241; called by muse, mutect2, varscan2
- TRRAP | c.5919G>A p.V1973= (on ENST00000359863 / NM_001244580.1; = p.V1955= on NM_003496.3) | Splice Region (SNP) | VAF 28/60 reads (47%) | catalogued as rs1554419691, COSV62853042; called by muse, mutect2, varscan2
- TSHZ3 | c.1313T>C p.L438P | Missense Mutation (SNP) | VAF 94/348 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV53680868; called by muse, mutect2, varscan2
- TTC7B | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 156/350 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as COSV60638118; called by muse, mutect2, varscan2
- TTN | c.38465C>T p.S12822L (on ENST00000591111; = p.S5398L on NM_003319.4) | Missense Mutation (SNP) | VAF 68/271 reads (25%) | PolyPhen benign (0.052); catalogued as COSV60300909; called by muse, mutect2, varscan2
- UBE2K | c.167_171del p.Y56Sfs*12 | Frame Shift Del (DEL) | VAF 97/170 reads (57%) | catalogued as COSV54692836; called by mutect2, pindel, varscan2
- UBR4 | c.10832G>T p.R3611L | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (0.953); catalogued as COSV64398104; called by muse, mutect2, varscan2
- USP34 | c.3481C>G p.L1161V | Missense Mutation (SNP) | VAF 14/348 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101276445; called by muse, mutect2
- USP54 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 126/368 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV60444239; called by muse, mutect2, varscan2
- WWC2 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV66715664; called by muse, mutect2, varscan2
- ZC2HC1A | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.422); catalogued as COSV99803625; called by muse, mutect2
- ZMAT4 | c.121A>G p.K41E | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99907767; called by muse, mutect2
- ZNF181 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as rs778812128, COSV67626360; called by muse, mutect2, varscan2
- ZNF224 | c.1547A>T p.K516M | Missense Mutation (SNP) | VAF 15/239 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV100425278; called by muse, mutect2
- ZNF233 | c.1565A>C p.H522P | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as COSV100491999; called by muse, mutect2
- ZNF337 | c.1687C>A p.Q563K | Missense Mutation (SNP) | VAF 38/400 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99429931; called by muse, mutect2
- ZNF345 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 40/386 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59325113; called by muse, mutect2, varscan2
- ZNF45 | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54194490; called by muse, mutect2, varscan2
- ZNF568 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV100451085; called by muse, mutect2
- ZNF804A | c.3023A>T p.K1008I | Missense Mutation (SNP) | VAF 13/390 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100165602; called by muse, mutect2
- ZSCAN31 | c.812A>T p.E271V | Missense Mutation (SNP) | VAF 17/270 reads (6%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.971); catalogued as COSV100716791; called by muse, mutect2
- ZSWIM2 | c.350A>T p.Q117L | Missense Mutation (SNP) | VAF 15/352 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV99719753; called by muse, mutect2
- ATP6V0A1 | c.1955T>C p.L652P | Missense Mutation (SNP) | VAF 9/231 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2
- FCGBP | c.725T>C p.L242P | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HCK | c.1539C>A p.D513E | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); called by muse, mutect2
- KIFC1 | c.590_604del p.A197_Q201del | In Frame Del (DEL) | VAF 24/157 reads (15%) | called by mutect2, pindel, varscan2
- MRC1 | c.3546T>A p.D1182E | Missense Mutation (SNP) | VAF 239/1105 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TBX22 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.012); called by muse, mutect2
- ADIPOR1 | c.435C>T p.F145= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as rs756017133, COSV61850784; called by muse, mutect2
- AOX1 | c.762A>G p.E254= | Silent (SNP) | VAF 33/434 reads (8%) | catalogued as COSV101021558; called by muse, mutect2
- BIRC3 | c.369A>G p.S123= | Silent (SNP) | VAF 77/519 reads (15%) | catalogued as COSV54819557; called by muse, mutect2, varscan2
- BPTF | c.6111A>C p.A2037= | Silent (SNP) | VAF 43/179 reads (24%) | catalogued as COSV100073510; called by muse, mutect2, varscan2
- CARF | c.168T>C p.N56= | Silent (SNP) | VAF 42/277 reads (15%) | catalogued as COSV57549620; called by muse, mutect2, varscan2
- CCDC22 | c.513G>T p.V171= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100879724; called by muse, mutect2
- CEP43 | c.564G>A p.Q188= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV100835514; called by muse, mutect2
- CEP63 | c.501A>T p.V167= | Silent (SNP) | VAF 34/201 reads (17%) | catalogued as COSV59678993; called by muse, mutect2, varscan2
- CEP85L | c.913C>A p.R305= | Silent (SNP) | VAF 20/237 reads (8%) | catalogued as COSV100682463, COSV62645920; called by muse, mutect2
- CHRM3 | c.768G>A p.K256= | Silent (SNP) | VAF 14/232 reads (6%) | catalogued as COSV99697027; called by muse, mutect2
- CIT | c.1995A>G p.A665= | Silent (SNP) | VAF 98/653 reads (15%) | catalogued as COSV55881178; called by muse, mutect2, varscan2
- CKAP5 | c.5517G>A p.K1839= (on ENST00000529230 / NM_001008938.4; = p.K1779= on NM_014756.3) | Silent (SNP) | VAF 37/378 reads (10%) | catalogued as COSV100370216; called by muse, mutect2, varscan2
- CLDN7 | c.339G>T p.V113= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV63040138; called by muse, mutect2, varscan2
- CNP | c.855C>G p.T285= | Silent (SNP) | VAF 15/167 reads (9%) | catalogued as COSV100347356; called by muse, mutect2
- COL15A1 | c.1302G>A p.G434= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV66648631; called by muse, mutect2, varscan2
- CRIM1 | c.1725C>T p.I575= | Silent (SNP) | VAF 18/324 reads (6%) | catalogued as COSV99751965; called by muse, mutect2
- CYP3A5 | c.303C>G p.V101= | Silent (SNP) | VAF 14/281 reads (5%) | catalogued as COSV56120107; called by muse, mutect2
- DYNC2H1 | c.8367C>T p.F2789= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs1462502493, COSV62105033; called by muse, mutect2, varscan2
- ENO1 | c.534C>T p.F178= | Silent (SNP) | VAF 13/124 reads (10%) | catalogued as rs747481520, COSV52305370; called by muse, mutect2, varscan2
- ENPP4 | c.495T>C p.N165= | Silent (SNP) | VAF 55/538 reads (10%) | catalogued as COSV58089901; called by muse, mutect2, varscan2
- EPB42 | c.2076A>G p.*692= (on ENST00000441366 / NM_001114134.2; = p.*722= on NM_000119.3) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100281418; called by muse, mutect2, varscan2
- FAM193A | c.2574C>T p.S858= | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as rs769630221, COSV61198126; called by muse, mutect2, varscan2
- FAT1 | c.8676T>C p.H2892= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV101498570; called by muse, mutect2, varscan2
- HAAO | c.27C>T p.A9= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as rs1289780249, COSV99685121; called by muse, mutect2, varscan2
- HERC2 | c.6486C>T p.L2162= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs780073146, COSV55314214, COSV55346493; called by muse, mutect2, varscan2
- HMGCLL1 | c.561C>A p.S187= | Silent (SNP) | VAF 20/199 reads (10%) | catalogued as COSV51450977; called by muse, mutect2
- IGF2BP3 | c.1023G>A p.E341= | Silent (SNP) | VAF 39/347 reads (11%) | catalogued as COSV51692242; called by muse, mutect2, varscan2
- IGLV7-46 | c.126C>G p.G42= | Silent (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- IL6ST | c.759A>T p.I253= | Silent (SNP) | VAF 14/119 reads (12%) | catalogued as COSV61142746; called by muse, mutect2, varscan2
- KRT14 | c.1044G>A p.Q348= | Silent (SNP) | VAF 63/102 reads (62%) | catalogued as COSV51422985; called by muse, mutect2, varscan2
- MAP2 | c.1878C>G p.S626= | Silent (SNP) | VAF 21/166 reads (13%) | catalogued as COSV52305728; called by muse, mutect2, varscan2
- MDN1 | c.14526T>C p.G4842= | Silent (SNP) | VAF 59/346 reads (17%) | catalogued as COSV65529172; called by muse, mutect2, varscan2
- MED12L | c.957C>T p.H319= | Silent (SNP) | VAF 16/350 reads (5%) | catalogued as COSV99850804; called by muse, mutect2
- METTL17 | c.1086G>A p.K362= | Silent (SNP) | VAF 34/296 reads (11%) | catalogued as COSV53870936; called by muse, mutect2, varscan2
- MZF1 | c.375G>A p.E125= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs1214146320, COSV53043060; called by muse, mutect2, varscan2
- NEFH | c.1962C>T p.S654= | Silent (SNP) | VAF 40/403 reads (10%) | called by muse, mutect2, varscan2
- NINL | c.759G>T p.V253= | Silent (SNP) | VAF 35/153 reads (23%) | catalogued as rs752318836, COSV54007842; called by muse, mutect2, varscan2
- NLRP4 | c.1311A>T p.I437= | Silent (SNP) | VAF 10/159 reads (6%) | catalogued as COSV100015311; called by muse, mutect2
- NUP210L | c.120C>T p.N40= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99665897, COSV99666098; called by muse, mutect2, varscan2
- OR10Q1 | c.723G>A p.R241= | Silent (SNP) | VAF 57/112 reads (51%) | catalogued as COSV57471871; called by muse, mutect2, varscan2
- OR2H2 | c.825C>T p.F275= | Silent (SNP) | VAF 37/414 reads (9%) | catalogued as COSV100589338; called by muse, mutect2
- OR2L3 | c.45A>T p.G15= | Silent (SNP) | VAF 110/2452 reads (4%) | catalogued as COSV100741870; called by muse, mutect2
- PCDHA5 | c.1191G>A p.V397= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV65357073; called by muse, mutect2, varscan2
- PGBD1 | c.2085C>T p.I695= | Silent (SNP) | VAF 69/484 reads (14%) | catalogued as COSV52555794; called by muse, mutect2, varscan2
- POLR3B | c.87G>T p.L29= | Silent (SNP) | VAF 37/226 reads (16%) | catalogued as COSV57283924; called by muse, mutect2, varscan2
- PSMF1 | c.48C>A p.T16= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV99850165; called by muse, mutect2
- RB1CC1 | c.759T>G p.S253= | Silent (SNP) | VAF 39/345 reads (11%) | catalogued as rs756655906, COSV50270968; called by muse, mutect2, varscan2
- SEMA6A | c.1164C>T p.T388= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV99145485; called by muse, mutect2
- SLC17A6 | c.492C>A p.T164= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as COSV99580415; called by muse, mutect2, varscan2
- SLC17A6 | c.493C>T p.L165= | Silent (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- SOST | c.630G>A p.E210= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- SPATA31A1 | c.1161G>A p.E387= | Silent (SNP) | VAF 40/593 reads (7%) | called by muse, mutect2
- SV2B | c.426G>C p.L142= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV57701689; called by muse, mutect2, varscan2
- TPD52L2 | c.330T>A p.S110= | Silent (SNP) | VAF 28/188 reads (15%) | catalogued as COSV53864234; called by muse, mutect2, varscan2
- TRIP12 | c.4830C>T p.G1610= | Silent (SNP) | VAF 57/178 reads (32%) | catalogued as COSV52271772; called by muse, mutect2, varscan2
- TTN | c.80931A>C p.G26977= (on ENST00000591111; = p.G19553= on NM_003319.4) | Silent (SNP) | VAF 31/166 reads (19%) | catalogued as COSV60300877; called by muse, mutect2, varscan2
- TTN | c.12043C>T p.L4015= (on ENST00000591111; = p.L3969= on NM_003319.4) | Silent (SNP) | VAF 18/245 reads (7%) | catalogued as rs780049225, COSV100587585; called by muse, mutect2
- UGCG | c.726G>A p.A242= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as rs755578705, COSV65336427; called by muse, mutect2, varscan2
- ZAN | c.6999C>G p.V2333= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100768905; called by muse, mutect2
- ZNF502 | c.1104A>G p.K368= | Silent (SNP) | VAF 20/242 reads (8%) | catalogued as COSV99939513; called by muse, mutect2
- BMP1 | c.2107+1786A>T | Intron (SNP) | VAF 10/139 reads (7%) | catalogued as COSV100108746; called by muse, mutect2
- CD300LB | c.-97C>G | 5'UTR (SNP) | VAF 23/110 reads (21%) | catalogued as COSV58726346; called by muse, mutect2, varscan2
- MIR802 | n.28G>T | RNA (SNP) | VAF 10/250 reads (4%) | called by muse, mutect2
- MOBP | c.*43G>C | 3'UTR (SNP) | VAF 17/247 reads (7%) | catalogued as COSV100215417, COSV100215600; called by muse, mutect2
- OR3A4P | n.830C>G | RNA (SNP) | VAF 62/324 reads (19%) | called by muse, mutect2, varscan2
- OR56A4 | c.-2G>T | 5'UTR (SNP) | VAF 14/202 reads (7%) | catalogued as COSV100417392; called by muse, mutect2
